Somatic mutation profile of tumor specimen TCGA-D7-A4YU-01A (aliquot TCGA-D7-A4YU-01A-21D-A25D-08) from TCGA case TCGA-D7-A4YU, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 73.3 years (26,781 days).
Specimen TCGA-D7-A4YU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7c85a99-6f75-461f-b75e-b34ef3ce99c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A4YU-10A (Blood Derived Normal), aliquot TCGA-D7-A4YU-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b79abf8d-7cc8-4ed7-ac85-08c229d5f39c

The open-access MAF lists 226 somatic variants for this specimen: 181 protein-altering or splice-affecting, 39 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 159, Silent 39, Nonsense Mutation 11, Splice Site 3, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 2, RNA 2, In Frame Ins 1, Intron 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 25/159 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 43/135 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC024598.1 | c.1237A>C p.S413R | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs1391043865, COSV60823996; called by muse, mutect2, varscan2
- ACOXL | c.157A>G p.K53E | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61324323; called by muse, mutect2, varscan2
- ADAM19 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs369868105; called by muse, mutect2, varscan2
- ADAMTS12 | c.2470C>A p.Q824K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV61262056; called by muse, mutect2, varscan2
- ADAMTS19 | c.3224A>C p.K1075T | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1278081498, COSV50745195; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs562929854, COSV52814957; called by muse, mutect2
- AMIGO3 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV57538407; called by muse, mutect2
- ANO7 | c.2083G>A p.D695N (on ENST00000274979; = p.D641N on NM_001370694.2) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as rs752516742, COSV51471233; called by muse, mutect2
- ARID1A | c.4101+1G>C p.X1367_splice | Splice Site (SNP) | VAF 35/158 reads (22%) | catalogued as COSV61375328, COSV61387522; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 24/123 reads (20%) | catalogued as rs758608743; called by mutect2, varscan2
- ARPP21 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs376713321, COSV51793709; called by muse, mutect2, varscan2
- BAZ2B | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58599923; called by muse, mutect2, varscan2
- BBX | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as rs761415898, COSV57883689; called by muse, mutect2, varscan2
- BLCAP | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs1384184662, COSV50351000; called by muse, mutect2, varscan2
- BOC | c.2608G>A p.V870I | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.234); catalogued as rs116501937; called by muse, mutect2, varscan2
- CCNA1 | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV55221250; called by muse, mutect2
- CD5L | c.778C>A p.L260M | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV63821877; called by muse, mutect2
- CDC25C | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV60399245; called by muse, mutect2, varscan2
- CDH1 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55731620, COSV55731862; called by muse, mutect2, varscan2
- CDH10 | c.2168T>C p.L723P | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.218); catalogued as rs763423183, COSV100053397, COSV52579394, COSV52582499; called by muse, mutect2, varscan2
- CELF4 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58452371; called by muse, mutect2, varscan2
- CENPF | c.4584C>A p.C1528* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV65274662; called by muse, mutect2, varscan2
- CHML | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV59363937; called by muse, mutect2, varscan2
- COL1A2 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.575); catalogued as COSV51957371; called by muse, mutect2, varscan2
- CPEB1 | c.204A>C p.E68D (on ENST00000617958; = p.E8D on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV71604389; called by muse, mutect2
- CPXCR1 | c.295A>T p.K99* | Nonsense Mutation (SNP) | VAF 13/20 reads (65%) | catalogued as COSV52162079; called by muse, mutect2, varscan2
- CR1 | c.3802G>T p.G1268C | Missense Mutation (SNP) | VAF 52/284 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65465866; called by mutect2, varscan2
- CRYGD | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as COSV52205142, COSV52205196; called by muse, mutect2, varscan2
- CSPG4 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100413715; called by muse, mutect2, varscan2
- CTAGE1 | c.2164G>A p.V722I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as rs760363760, COSV66943363; called by muse, mutect2, varscan2
- CYP7B1 | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59587462; called by muse, mutect2
- DAGLA | c.2410C>T p.R804W | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs774883579, COSV57195675; called by muse, mutect2, varscan2
- DCAF12L2 | c.1142A>C p.K381T | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV100758799, COSV63581446, COSV63581842; called by muse, mutect2, varscan2
- DCLRE1B | c.789C>A p.S263R | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV65812140, COSV65812678; called by muse, mutect2, varscan2
- DDX23 | c.2405A>G p.Q802R | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV56398116; called by muse, mutect2
- DGKI | c.2823G>A p.K941= | Splice Region (SNP) | VAF 13/60 reads (22%) | catalogued as COSV55948037; called by muse, mutect2, varscan2
- DLL1 | c.2003A>C p.Q668P | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV64537388; called by muse, mutect2, varscan2
- DNER | c.2107G>T p.G703* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV59165247; called by muse, mutect2, varscan2
- DPEP3 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.216); catalogued as COSV52051192; called by muse, mutect2, varscan2
- E2F7 | c.1011C>G p.D337E | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59739467; called by muse, mutect2, varscan2
- EDAR | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs768660721, COSV51502365; called by muse, mutect2, varscan2
- EOGT | c.1301T>G p.L434R (on ENST00000383701 / NM_001278689.2; = p.L350R on NM_173654.3) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55151055; called by muse, mutect2, varscan2
- EPG5 | c.2281G>A p.E761K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV56348971, COSV99956491; called by muse, mutect2, varscan2
- FAM135B | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50525604; called by muse, mutect2, varscan2
- FAM13C | c.1352A>C p.D451A | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53247760, COSV53251833; called by muse, mutect2
- FAM81B | c.426C>G p.C142W | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51982666; called by muse, mutect2
- FAT3 | c.8707T>G p.S2903A | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.578); catalogued as COSV53105227; called by muse, mutect2, varscan2
- FBN1 | c.1398T>G p.I466M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100354659; called by muse, mutect2, varscan2
- FBN1 | c.1397T>A p.I466N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as COSV100354661; called by muse, mutect2, varscan2
- FBN1 | c.895T>C p.C299R | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57315519; called by muse, mutect2, varscan2
- FCHSD2 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs147782509; called by muse, mutect2, varscan2
- FLACC1 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV53783610; called by muse, mutect2, varscan2
- FZD10 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as rs1566096577, COSV57472117; called by muse, mutect2, varscan2
- GABRE | c.1099A>C p.N367H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as COSV64819529; called by muse, mutect2, varscan2
- GCC1 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58462445; called by muse, mutect2, varscan2
- GPR148 | c.99C>A p.S33R | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1178877150, COSV59308153; called by muse, mutect2, varscan2
- GRM8 | c.2570A>C p.K857T | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as COSV100281640, COSV58822667; called by muse, mutect2, varscan2
- HSP90AA1 | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53488462; called by muse, mutect2, varscan2
- ICE2 | c.1429G>T p.G477C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV55031157; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1648G>T p.E550* (on ENST00000485419 / NM_001197113.1; = p.E474* on NM_014575.3) | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV61844022; called by muse, mutect2, varscan2
- IRX5 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs1200689396, COSV58058838; called by mutect2, varscan2
- ITGA1 | c.2921A>G p.N974S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV50881144; called by muse, mutect2, varscan2
- KCNG1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV65368961; called by muse, mutect2
- KCNK3 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); catalogued as COSV57192378; called by muse, mutect2, varscan2
- KCNMA1 | c.2573G>A p.R858Q (on ENST00000286628 / NM_001161352.2; = p.R800Q on NM_002247.4) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs773879015, COSV54228186; called by muse, mutect2, varscan2
- KCTD9 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.146); catalogued as COSV55339984; called by muse, mutect2, varscan2
- KHDRBS2 | c.960A>T p.E320D | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.99); catalogued as COSV55439851, COSV55449017, COSV99836744; called by muse, mutect2, varscan2
- KIF20B | c.1979G>T p.C660F | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as COSV53306295; called by muse, mutect2, varscan2
- KLHL4 | c.1418T>C p.V473A | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV64141890, COSV64145034; called by muse, mutect2, varscan2
- KRT10 | c.488A>G p.K163R | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV54089574; called by muse, mutect2, varscan2
- KRT20 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as rs1322970219, COSV51424721; called by muse, mutect2
- LAMA4 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs372074151; called by muse, mutect2, varscan2
- LMAN2L | c.312T>A p.C104* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV53841560; called by muse, mutect2, varscan2
- LRP1B | c.7387+1G>T p.X2463_splice | Splice Site (SNP) | VAF 23/136 reads (17%) | catalogued as COSV67213430; called by muse, mutect2, varscan2
- LRRC31 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760486211, COSV52980637, COSV52983014; called by muse, varscan2
- LRRC61 | c.374A>C p.E125A | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs772862456, COSV56231160; called by muse, mutect2, varscan2
- MDC1 | c.1115G>C p.S372T | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV64524400; called by muse, mutect2, varscan2
- MED12 | c.2882G>A p.R961Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs766598254, COSV61338733; called by muse, mutect2, varscan2
- MED12L | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.129); catalogued as rs774785880, COSV56377455; called by muse, mutect2, varscan2
- MED12L | c.4297G>T p.A1433S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV56377469; called by muse, mutect2
- MKNK2 | c.419+2T>A p.X140_splice | Splice Site (SNP) | VAF 10/54 reads (19%) | catalogued as COSV51732201; called by muse, mutect2, varscan2
- MUC4 | c.12875C>T p.S4292F (on ENST00000463781 / NM_018406.7; = p.S56F on NM_004532.6) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as rs1452626313, COSV57789797; called by muse, mutect2, varscan2
- NAA25 | c.2320A>G p.I774V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55704008; called by mutect2, varscan2
- NEBL | c.1934T>G p.V645G | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV65802732; called by muse, mutect2, varscan2
- NEUROD2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.486); catalogued as rs1370534692, COSV56910974; called by muse, mutect2, varscan2
- NME8 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52249742, COSV99554010; called by muse, mutect2, varscan2
- NOM1 | c.2534C>G p.A845G | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV51979949; called by muse, mutect2, varscan2
- NPAS3 | c.2684C>T p.T895M (on ENST00000356141 / NM_001164749.2; = p.T863M on NM_022123.3) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV60832682; called by muse, mutect2
- NPW | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.541); catalogued as COSV61586140; called by muse, mutect2
- NR1H2 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs772703025, COSV53800669; called by muse, mutect2
- NUAK1 | c.1171A>C p.K391Q | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV54602898; called by muse, mutect2, varscan2
- NUDT22 | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV54173195; called by muse, mutect2, varscan2
- NXPE4 | c.263T>C p.F88S | Missense Mutation (SNP) | VAF 80/268 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64943717; called by muse, mutect2, varscan2
- ODF2L | c.1172T>A p.V391D (on ENST00000317336; = p.V362D on NM_020729.3) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV54015296; called by muse, mutect2, varscan2
- OLFM3 | c.257T>G p.L86R (on ENST00000338858 / NM_001288821.1; = p.L66R on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58796124, COSV58798328; called by muse, mutect2, varscan2
- OR10A4 | c.199T>G p.L67V | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65841945, COSV65842200; called by muse, mutect2, varscan2
- OR14I1 | c.56G>T p.W19L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV61199546; called by mutect2, varscan2
- OR2M5 | c.300A>C p.Q100H | Missense Mutation (SNP) | VAF 83/388 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs764988039, COSV63546164; called by muse, mutect2, varscan2
- OR52A5 | c.427T>G p.L143V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV56613991, COSV56614404; called by muse, mutect2, varscan2
- OR52E6 | c.848T>A p.V283D | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61431933; called by muse, mutect2, varscan2
- OR7D4 | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV58071618; called by muse, mutect2, varscan2
- OR9A4 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs782628084, COSV71885364; called by muse, mutect2, varscan2
- PACRG | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs543247575, COSV61303923, COSV61310477; called by muse, mutect2, varscan2
- PAK6 | c.1079G>A p.S360N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV53045443; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.751G>A p.E251K (on ENST00000259318 / NM_001136562.3; = p.E482K on NM_007203.5) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765456063, COSV52175740; called by muse, mutect2, varscan2
- PAPPA | c.1640A>C p.N547T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60282371; called by muse, mutect2, varscan2
- PCLO | c.11589A>C p.E3863D | Missense Mutation (SNP) | VAF 81/349 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV61632414; called by muse, mutect2, varscan2
- PIP5K1C | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV58952116; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1039G>T p.G347W | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65047856; called by muse, mutect2
- PNMA3 | c.1053A>T p.E351D | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV64722224; called by muse, mutect2, varscan2
- POSTN | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65712034; called by muse, mutect2, varscan2
- PREPL | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs778873576, COSV53216445; called by muse, mutect2, varscan2
- PTPRB | c.708G>C p.E236D | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.157); catalogued as COSV57699420; called by muse, mutect2, varscan2
- PTPRM | c.2982C>G p.I994M | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59856741; called by muse, mutect2, varscan2
- PTPRZ1 | c.1804A>G p.N602D | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV66435748; called by muse, mutect2, varscan2
- QRSL1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV64687451; called by muse, mutect2, varscan2
- RAPGEF6 | c.1813G>C p.A605P | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV57245396, COSV57253267; called by muse, mutect2, varscan2
- RELN | c.8358G>A p.W2786* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV58999710; called by muse, mutect2, varscan2
- RHOA | c.123C>G p.N41K | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV101371131, COSV69042359; called by muse, varscan2
- RIPK3 | c.1493A>G p.E498G | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV53475198; called by mutect2, varscan2
- RNF111 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.791); catalogued as rs1465843718, COSV62085602; called by muse, mutect2, varscan2
- RNF152 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.133); catalogued as COSV57185264; called by muse, mutect2, varscan2
- RPGR | c.533G>C p.S178T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.034); catalogued as COSV100139892; called by muse, mutect2
- RUBCNL | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as rs993269341, COSV59787844; called by muse, mutect2
- SAFB | c.2729G>A p.R910H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.013); catalogued as rs764621843, COSV52651189; called by muse, varscan2
- SDK1 | c.5007G>T p.K1669N | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV67366932; called by muse, mutect2, varscan2
- SDK1 | c.5353G>A p.G1785R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375894303; called by muse, varscan2
- SEMA3A | c.2188C>T p.R730* | Nonsense Mutation (SNP) | VAF 22/108 reads (20%) | catalogued as rs1489988466, COSV54865282; called by muse, mutect2, varscan2
- SEMA5A | c.3062A>C p.H1021P | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.333); catalogued as COSV66791664; called by muse, mutect2, varscan2
- SEZ6 | c.2279A>G p.E760G | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV57979472; called by muse, mutect2, varscan2
- SFMBT2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760397823, COSV62808284; called by muse, mutect2, varscan2
- SLC7A6OS | c.886_888del p.K296del | In Frame Del (DEL) | VAF 23/126 reads (18%) | catalogued as rs747445254; called by mutect2, pindel, varscan2
- SLC8A1 | c.182T>C p.L61S | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60479229; called by muse, mutect2, varscan2
- SLCO2A1 | c.1835G>A p.G612D | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.625); catalogued as COSV60485487; called by muse, mutect2, varscan2
- SOST | c.233A>C p.Y78S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.55); catalogued as COSV57012543; called by muse, mutect2, varscan2
- SOX4 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV55193105; called by muse, mutect2, varscan2
- SPOCK1 | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.932); catalogued as COSV56447502; called by muse, mutect2, varscan2
- SRY | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV67170384; called by muse, mutect2, varscan2
- STK24 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as rs1218438785, COSV64822844; called by muse, varscan2
- STX11 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62448519, COSV62450647; called by muse, mutect2, varscan2
- SYT4 | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV54900119; called by muse, mutect2, varscan2
- TBPL1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs201622346, COSV51599744; called by muse, mutect2, varscan2
- THEG | c.912C>A p.A304= | Splice Region (SNP) | VAF 38/212 reads (18%) | catalogued as COSV61073755; called by muse, mutect2, varscan2
- THSD7B | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV55681637; called by muse, mutect2, varscan2
- TIAM1 | c.4343G>A p.R1448Q | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.54); catalogued as rs769596231, COSV54549110, COSV54554408; called by muse, varscan2
- TIGIT | c.207T>G p.C69W | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV67328845; called by muse, mutect2, varscan2
- TMCC3 | c.358C>G p.Q120E | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54154030; called by muse, mutect2, varscan2
- TMPRSS15 | c.2494T>G p.L832V | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as rs1231579914, COSV53039182, COSV53041945; called by muse, mutect2, varscan2
- TTN | c.97958C>A p.S32653* (on ENST00000591111; = p.S25229* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV60023988; called by muse, mutect2, varscan2
- TTN | c.63248A>G p.Y21083C (on ENST00000591111; = p.Y13659C on NM_003319.4) | Missense Mutation (SNP) | VAF 31/121 reads (26%) | PolyPhen probably damaging (0.999); catalogued as rs1387896930, COSV60024010; called by muse, mutect2, varscan2
- TUBB4A | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51154298; called by muse, mutect2
- TYW1 | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62752415; called by muse, mutect2, varscan2
- URGCP | c.1795A>G p.T599A (on ENST00000453200 / NM_001077663.3; = p.T590A on NM_017920.4) | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV56247209; called by muse, mutect2, varscan2
- UTRN | c.3477A>C p.E1159D | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as COSV62334276; called by muse, mutect2, varscan2
- VCAN | c.8983A>C p.S2995R | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.69); catalogued as COSV54104052; called by muse, mutect2
- VSTM2A | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV56493529; called by muse, mutect2, varscan2
- WASF2 | c.478T>C p.W160R | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71005442; called by muse, mutect2, varscan2
- WDR17 | c.2785T>A p.S929T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV54573165; called by muse, mutect2, varscan2
- XIRP1 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs752430488, COSV61138214; called by muse, mutect2, varscan2
- YWHAE | c.403T>A p.F135I | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV51982341; called by muse, mutect2, varscan2
- ZBBX | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56785362; called by muse, mutect2
- ZBTB7A | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs747390241, COSV59327136; called by muse, mutect2, varscan2
- ZNF165 | c.1366T>A p.Y456N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV66102374; called by muse, mutect2, varscan2
- ZNF208 | c.641C>A p.S214* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV68104601; called by mutect2, varscan2
- ZNF236 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1466968852, COSV53487318; called by muse, mutect2, varscan2
- ZNF257 | c.848A>C p.K283T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV71307083; called by muse, mutect2, varscan2
- ZNF296 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs143888878; called by muse, mutect2, varscan2
- ZNF521 | c.1589A>G p.E530G | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1471109726, COSV64126357; called by muse, mutect2, varscan2
- ZNF521 | c.1027A>G p.S343G | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV64126363; called by muse, mutect2, varscan2
- ZNF615 | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV65033005; called by muse, varscan2
- ZNF790 | c.636A>C p.E212D | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV63212399; called by muse, mutect2, varscan2
- ZNF85 | c.374A>C p.K125T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV56021564, COSV56022043; called by muse, varscan2
- ZPLD1 | c.866T>A p.M289K (on ENST00000466937 / NM_001329788.1; = p.M305K on NM_175056.2) | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV60353291; called by muse, mutect2, varscan2
- KIF11 | c.2790_2791del p.S931Lfs*11 | Frame Shift Del (DEL) | VAF 29/94 reads (31%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.354A>C p.E118D | Missense Mutation (SNP) | VAF 109/481 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RBM10 | c.967del p.Y323Tfs*12 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | called by mutect2, varscan2*
- RHOJ | c.620dup p.H208Sfs*21 | Frame Shift Ins (INS) | VAF 10/89 reads (11%) | called by mutect2, pindel, varscan2
- RNF103 | c.274_276dup p.A92dup | In Frame Ins (INS) | VAF 8/68 reads (12%) | called by mutect2, pindel, varscan2
- ABCA7 | c.2235C>A p.G745= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- AHNAK | c.2037A>G p.K679= | Silent (SNP) | VAF 27/174 reads (16%) | catalogued as rs1565245201, COSV57212170; called by muse, mutect2, varscan2
- ANKRD13B | c.1248A>G p.P416= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV61470763; called by muse, mutect2, varscan2
- BTBD17 | c.888G>A p.S296= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1323991693, COSV64729700; called by muse, mutect2, varscan2
- CA6 | c.792C>A p.R264= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV66262073; called by muse, mutect2, varscan2
- CCM2L | c.72C>T p.A24= | Silent (SNP) | VAF 16/248 reads (6%) | catalogued as rs759116917, COSV52950176; called by muse, mutect2
- CEP192 | c.2436T>G p.S812= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV58063436; called by muse, mutect2, varscan2
- CNTNAP1 | c.1215C>T p.D405= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as COSV52850129; called by muse, mutect2, varscan2
- COL11A1 | c.5301C>A p.V1767= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100616108; called by muse, mutect2, varscan2
- CPT1C | c.492G>A p.L164= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99773388; called by muse, mutect2, varscan2
- CRACDL | c.1140G>A p.P380= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs905422583, COSV67407880; called by mutect2, varscan2
- CRYBA2 | c.237C>T p.S79= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs373560575; called by mutect2, varscan2
- DCC | c.3879C>T p.F1293= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs1211794693, COSV71426478; called by muse, mutect2, varscan2
- DDX51 | c.1767C>T p.Y589= | Silent (SNP) | VAF 43/140 reads (31%) | catalogued as rs762033125, COSV57958059; called by muse, mutect2, varscan2
- DLL1 | c.1116C>T p.D372= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs757878599, COSV64537393; called by muse, mutect2, varscan2
- ERBB4 | c.3270A>G p.E1090= | Silent (SNP) | VAF 38/166 reads (23%) | catalogued as COSV61483958, COSV61511878; called by muse, mutect2, varscan2
- FRMPD4 | c.201G>A p.E67= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV66214386; called by muse, mutect2, varscan2
- HIVEP2 | c.2106C>T p.S702= | Silent (SNP) | VAF 17/139 reads (12%) | catalogued as rs748901140, COSV50010462; ClinVar: likely benign; called by muse, mutect2, varscan2
- HNRNPA0 | c.879C>T p.G293= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV59246533; called by muse, mutect2, varscan2
- KRCC1 | c.744G>A p.E248= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV61251435; called by muse, mutect2, varscan2
- KRT73 | c.630C>T p.S210= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as rs116369374, COSV59838771; called by muse, mutect2, varscan2
- MCHR2 | c.672T>G p.T224= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV56002371, COSV56002606, COSV99911365; called by muse, varscan2
- MPHOSPH8 | c.1884C>T p.N628= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs770395972, COSV64055409; called by muse, mutect2, varscan2
- MPP3 | c.327G>A p.T109= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as rs34890360; called by muse, mutect2, varscan2
- MYCBP2 | c.12738C>T p.D4246= (on ENST00000357337; = p.D4284= on NM_015057.5) | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV62017367; called by muse, varscan2
- NTM | c.627G>A p.A209= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs192028313; called by muse, mutect2, varscan2
- OR8D2 | c.142T>C p.L48= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV62488432; called by muse, mutect2, varscan2
- PCDH18 | c.981A>G p.Q327= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV61266332, COSV61268397; called by muse, mutect2, varscan2
- PCDHA8 | c.2004G>A p.S668= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as COSV65326055; called by muse, mutect2, varscan2
- PCDHB16 | c.606G>A p.R202= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV53361621; called by muse, mutect2
- PDE3A | c.903C>T p.S301= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV62971313; called by muse, mutect2, varscan2
- PNPT1 | c.147G>C p.V49= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as COSV53177154; called by muse, mutect2
- RXFP3 | c.120C>T p.N40= | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as rs759874702, COSV57505338; called by muse, mutect2, varscan2
- SPTA1 | c.5097A>G p.Q1699= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV63752409, COSV63755786; called by muse, mutect2, varscan2
- SULT1E1 | c.96G>A p.A32= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs138937330; called by muse, mutect2, varscan2
- TLN2 | c.2724C>A p.A908= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100168758; called by muse, mutect2
- TMEM104 | c.1026C>T p.F342= | Silent (SNP) | VAF 61/189 reads (32%) | catalogued as rs562626910, COSV59108758, COSV59109202; called by muse, varscan2
- ZBTB49 | c.1107C>T p.C369= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV61924946; called by muse, mutect2, varscan2
- ZNF606 | c.1038T>C p.N346= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV62046337; called by muse, mutect2, varscan2
- C10orf95 | c.-27G>C | 5'UTR (SNP) | VAF 12/38 reads (32%) | catalogued as COSV53309257; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397855 T>C | 3'Flank (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- MIR520A | n.78G>T | RNA (SNP) | VAF 28/96 reads (29%) | called by muse, varscan2
- PRR12 | chr19:49594951 G>A | 5'Flank (SNP) | VAF 4/12 reads (33%) | catalogued as rs746376324, COSV55870130, COSV55870202; called by muse, mutect2
- RIMS2 | c.4064-21159T>C | Intron (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99167204; called by muse, mutect2, varscan2
- UBTFL2 | n.121C>T | RNA (SNP) | VAF 41/161 reads (25%) | catalogued as rs1392975320; called by muse, mutect2, varscan2
